Gene-level copy-number profile of tumor specimen TCGA-SI-A71O-06A from TCGA case TCGA-SI-A71O, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 29.3 years (10,710 days).
Specimen TCGA-SI-A71O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.57a669c7-179f-4c39-90a9-e169b95bcb13.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SI-A71O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89f07a8a-0995-4547-b7fd-b99885dddb1a

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 3,954; copy number 1: 26,601; copy number 2: 24,769; copy number 3: 3,365; copy number 4: 1,129; copy number 5: 110; copy number 6: 105; copy number 7: 190.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SI-A71O-06A-11D-A386-01): tumor purity 0.46, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1,246 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:214,725,646–215,138,626, 5 genes (within-gene range 0–1): BARD1, SNHG31, SNORA70I, RPL10P6, ABCA12.
- chr2:234,743,542–242,160,153, 167 genes (broad region; genes not listed).
- chr4:186,900,540–190,092,279, 63 genes (broad region; genes not listed).
- chr5:58,198–218,153, 7 genes: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3.
- chr5:178,764,861–178,842,235, 4 genes (within-gene range 0–1): AACSP1, AC126915.2, AC126915.1, AC126915.3.
- chr7:141,074,064–144,850,084, 210 genes (within-gene range 0–1) (broad region; genes not listed).
- chr7:147,671,711–159,233,377, 248 genes (broad region; genes not listed).
- chr8:150,584–2,165,552, 48 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr8:143,632,071–144,847,509, 90 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:20,532,552–20,533,339, 1 gene: AL163193.1.
- chr9:60,914,407–61,662,690, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr12:66,767–991,190, 25 genes: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr14:21,797,287–22,482,959, 52 genes (within-gene range 0–1): TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2.
- chr17:41,265,339–41,271,835, 2 genes (within-gene range 0–1): KRTAP9-6, KRTAP9-11P.
- chr22:26,521,996–30,207,195, 107 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:43,110,750–50,801,309, 199 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,899 genes in 66 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,127,287–179,836,124, 536 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr2:38,814–3,580,920, 62 genes, copy number 3–4 (broad region; genes not listed).
- chr3:11,745–551,657, 9 genes, copy number 3: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1.
- chr3:66,378,797–79,767,998, 149 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr3:102,099,244–109,977,767, 79 genes, copy number 3 (broad region; genes not listed).
- chr3:110,727,021–115,147,288, 84 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:114,930,541–117,139,389, 16 genes, copy number 3 (within-gene range 2–3): YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1, LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1.
- chr3:161,816,909–164,002,465, 9 genes, copy number 3: AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1.
- chr4:1,617,915–34,335,351, 461 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr6:53,739,266–54,485,850, 12 genes, copy number 3: AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1.
- chr6:72,522,641–87,329,278, 206 genes, copy number 3–7 (broad region; genes not listed).
- chr7:47,275,154–50,793,462, 38 genes, copy number 4 (within-gene range 2–4): TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1.
- chr7:68,640,798–69,597,493, 12 genes, copy number 3: AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr8:73,042,910–74,866,939, 48 genes, copy number 3 (within-gene range 2–3): AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15.
- chr9:134,078,904–134,844,843, 15 genes, copy number 3 (within-gene range 2–3): ARF4P1, BX649632.1, WDR5, RNU6ATAC, BX649601.1, LINC02247, AL354796.1, RXRA, MIR4669, AL669970.1, AL669970.3, AL669970.2, COL5A1, COL5A1-AS1, AL645768.1.
- chr11:55,262,155–55,537,924, 19 genes, copy number 4: TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P.
- chr11:60,785,333–61,161,615, 20 genes, copy number 3 (within-gene range 1–3): MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1.
- chr12:24,566,964–25,250,936, 20 genes, copy number 3: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:37,575,587–53,506,431, 443 genes, copy number 3–4 (broad region; genes not listed).
- chr13:18,467,172–20,091,829, 58 genes, copy number 3 (within-gene range 1–3): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2, ZMYM2.
- chr13:94,960,041–97,677,963, 37 genes, copy number 3–4: LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1.
- chr13:100,464,440–102,875,995, 37 genes, copy number 4–7: PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6, NALCN-AS1, ARF4P3, LINC00411, NALCN, ITGBL1, FGF14, AL160153.1, RNU1-24P, HMGB3P7, MIR2681, LIPT1P1, RNY1P2, MIR4705, RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5.
- chr14:55,559,072–56,730,535, 16 genes, copy number 3 (within-gene range 2–3): KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1, AL161757.2, AL161757.5, AL161757.1.
- chr14:83,017,106–88,470,350, 45 genes, copy number 3: AL359238.1, AL162872.1, RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1, GALC, SHLD2P2, RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1, KCNK10, SPATA7.
- chr14:100,480,952–106,875,071, 479 genes, copy number 3–7 (broad region; genes not listed).
- chr16:3,355,889–5,235,822, 85 genes, copy number 3 (broad region; genes not listed).
- chr16:8,537,605–9,156,881, 23 genes, copy number 3 (within-gene range 2–3): TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119.
- chr16:10,840,384–22,916,338, 339 genes, copy number 3–6 (broad region; genes not listed).
- chr17:49,132,460–49,995,224, 38 genes, copy number 3: B4GALNT2, AC069454.1, GNGT2, ABI3, PHOSPHO1, FLJ40194, MIR6129, ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3.
- chr17:50,094,065–54,478,168, 85 genes, copy number 3–4 (broad region; genes not listed).
- chr18:14,089,935–15,330,282, 49 genes, copy number 3: AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:54,142,133–54,525,563, 10 genes, copy number 3: AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1.
- chr18:63,871,692–65,652,053, 15 genes, copy number 3: SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1.
- chr18:73,151,241–75,868,252, 41 genes, copy number 3–6: LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922, DIPK1C, AC009704.3, CNDP2, AC009704.2, CNDP1, AC009704.1, LINC00909, ZNF407, AC015819.2, AC015819.1, AC015819.4, AC015819.3, AC015819.5, ZADH2, TSHZ1, AC116003.3, AC116003.1, SMIM21, AC116003.2, AC012101.2, AC012101.1, AC090812.1, AC090338.1, LINC01898, AC021506.1.
- chr19:4,815,932–8,778,861, 181 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr19:11,131,520–13,633,025, 161 genes, copy number 3–4 (within-gene range 3–5) (broad region; genes not listed).
- chr19:56,189,570–58,605,223, 178 genes, copy number 3 (broad region; genes not listed).
- chr21:12,999,676–14,210,891, 45 genes, copy number 3 (within-gene range 1–3): AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1.
- chr21:14,371,115–24,547,942, 127 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr22:16,405,330–25,520,854, 551 genes, copy number 3–4 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26,567. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
